Gene-level copy-number profile of tumor specimen TCGA-23-1022-01A from TCGA case TCGA-23-1022, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.9 years (24,798 days).
Specimen TCGA-23-1022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3a8b9a57-2f04-40bd-85e7-2385fa37a913.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1022-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f657190a-9d27-43d6-92f0-e2af2620a864

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,876; copy number 2: 20,715; copy number 3: 17,743; copy number 4: 8,151; copy number 5: 5,826; copy number 6: 1,479; copy number 7: 630; copy number 8: 248; copy number 9: 140.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1022-01A-02D-0428-01): tumor purity 0.89, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,323 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,373,711–161,766,227, 430 genes, copy number 5 (broad region; genes not listed).
- chr2:145,294,277–153,762,646, 97 genes, copy number 5 (broad region; genes not listed).
- chr2:173,871,653–204,507,672, 507 genes, copy number 5–9 (broad region; genes not listed).
- chr2:204,668,863–204,678,698, 1 gene, copy number 6: AC007736.1.
- chr3:156,747,343–168,095,924, 134 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:168,288,553–168,291,228, 1 gene, copy number 5: AC124893.1.
- chr3:170,418,868–170,860,380, 1 gene, copy number 5 (within-gene range 4–5): AC026316.4.
- chr3:170,448,639–198,222,513, 551 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr4:37,453,925–37,869,978, 9 genes, copy number 6: C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1.
- chr4:37,960,398–37,996,203, 2 genes, copy number 6: PTTG2, PSME2P4.
- chr5:66,507,380–68,087,494, 20 genes, copy number 5: LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1, CD180, AC010420.1, AC008459.1, AC112206.2, AC079467.1, AC112206.1, LINC02242, BCL9P1, AC112206.4, AC112206.3, AC106798.1, AC024581.1, AC024581.2, AC010376.1.
- chr7:108,147,623–111,562,517, 25 genes, copy number 6 (within-gene range 4–6): NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1.
- chr7:131,892,616–138,118,305, 83 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:140,241,870–154,894,285, 412 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:86,866,415–98,294,393, 168 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:99,873,200–145,066,685, 712 genes, copy number 5–7 (broad region; genes not listed).
- chr9:81,410,279–82,780,194, 22 genes, copy number 5 (within-gene range 4–5): RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4.
- chr10:44,712–21,293,011, 345 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr10:23,575,012–42,210,383, 276 genes, copy number 5–8 (broad region; genes not listed).
- chr10:115,093,365–115,948,999, 1 gene, copy number 5 (within-gene range 3–5): ATRNL1.
- chr10:115,819,842–120,070,159, 79 genes, copy number 5 (broad region; genes not listed).
- chr10:121,736,303–133,569,835, 201 genes, copy number 5–6 (broad region; genes not listed).
- chr10:133,575,122–133,589,413, 2 genes, copy number 6: OR6L1P, AL731769.1.
- chr11:71,428,193–135,075,908, 1,352 genes, copy number 5–7 (broad region; genes not listed).
- chr13:64,958,097–112,201,000, 528 genes, copy number 5–8 (broad region; genes not listed).
- chr15:75,369,379–75,455,842, 1 gene, copy number 6 (within-gene range 4–6): SIN3A.
- chr15:75,415,249–76,229,121, 31 genes, copy number 6 (within-gene range 4–6): AC105137.1, AC105137.2, PTPN9, AC105036.2, AC105036.1, AC105036.3, SNUPN, AC105020.3, AC105020.2, IMP3, AC105020.6, AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35, AC019294.2, PPIAP47, AC019294.3, MIR4313, AC019294.1, RN7SL319P, DNM1P49, UBE2Q2, RN7SL510P, FBXO22, NRG4, AC027104.1, TMEM266.
- chr15:88,636,153–101,933,350, 333 genes, copy number 5 (broad region; genes not listed).
- chr19:17,859,910–24,163,425, 306 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:32,581,190–33,175,799, 23 genes, copy number 5 (within-gene range 4–5): PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88.
- chr19:50,136,859–58,605,223, 651 genes, copy number 5 (broad region; genes not listed).
- chr20:30,214,765–37,179,588, 233 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:38,098,414–57,712,780, 437 genes, copy number 5 (broad region; genes not listed).
- chr22:15,290,718–21,064,168, 274 genes, copy number 5 (broad region; genes not listed).
- chr22:23,834,503–25,405,377, 75 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,283. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
